Somatic mutation profile of tumor specimen MBCproject_0093_T1_WES (aliquot MBCproject_0093_T1_WES_1) from CMI case MBCproject_0093, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 38.9 years (14,206 days).
Specimen MBCproject_0093_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b603a50-67d8-40d3-8604-f3063f1fbaaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCproject_0093_SALIVA (Saliva), aliquot MBCproject_0093_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11389202-bfb7-4f1b-bf5d-15531b3ac439

The open-access MAF lists 64 somatic variants for this specimen: 54 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 6, Frame Shift Del 2, 3'UTR 2, Splice Site 1, RNA 1, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs786202082, CD098502, COSV52704969, COSV52749634, COSV52761908, COSV52834111; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH8 | c.1178C>A p.S393* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV54851239; called by muse, mutect2, varscan2
- COL11A2 | c.2326C>T p.R776C (on ENST00000341947 / NM_080680.3; = p.R669C on NM_080679.2) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776701792, COSV59493332; called by muse, mutect2, varscan2
- CPNE9 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs745817621, COSV56068053, COSV99808553; called by muse, mutect2, varscan2
- DST | c.6822A>T p.K2274N | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV99751996; called by muse, mutect2, varscan2
- FCGR3B | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV54212531; called by muse, mutect2, varscan2
- MACF1 | c.19607C>A p.S6536Y (on ENST00000372915; = p.S4581Y on NM_012090.5) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as rs780899624; called by muse, mutect2, varscan2
- P2RY14 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs138908546; called by muse, mutect2, varscan2
- PAM | c.1298del p.K433Rfs*32 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | catalogued as rs1235994663; called by pindel, varscan2
- PGBD2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs747821752; called by muse, mutect2, varscan2
- RPGRIP1 | c.2489C>A p.T830N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV52845098; called by muse, mutect2
- SPRY4 | c.682C>T p.R228C (on ENST00000434127 / NM_001127496.3; = p.R251C on NM_030964.4) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1024075344, COSV59986864; called by muse, mutect2, varscan2
- SYNM | c.4387C>G p.Q1463E | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.967); catalogued as rs113821939; called by muse, mutect2, varscan2
- USH2A | c.11095G>C p.E3699Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as CM149929, COSV100241748; called by mutect2, varscan2
- XIRP2 | c.7555G>C p.E2519Q (on ENST00000628543; = p.E2694Q on NM_152381.6) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV54686237; called by muse, mutect2, varscan2
- ZFHX3 | c.8665C>G p.R2889G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs758610922; called by mutect2, varscan2
- AASS | c.1542G>C p.K514N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ALDH5A1 | c.1135A>C p.T379P | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD12 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ANKRD20A4P | c.77G>C p.G26A | Missense Mutation (SNP) | VAF 6/7 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- ARL6IP1 | c.449G>C p.W150S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ASTN1 | c.2804G>C p.S935T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- C4B | c.3896T>C p.F1299S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP410 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLDN2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH3 | c.8948A>G p.E2983G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by mutect2, varscan2
- DNTT | c.1227G>T p.L409F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ENOX2 | c.628G>A p.D210N (on ENST00000338144 / NM_001382520.1; = p.D181N on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- FAM171A1 | c.295T>G p.S99A | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FCRL1 | c.728A>T p.Y243F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FXR1 | c.1661C>A p.P554Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.483); called by muse, varscan2
- GOLGA4 | c.5994G>C p.M1998I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- KCMF1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNJ10 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.19606T>C p.S6536P (on ENST00000372915; = p.S4581P on NM_012090.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- MANBA | c.2244C>G p.F748L (on ENST00000642252; = p.F702L on NM_005908.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MYH3 | c.3577C>A p.L1193M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- MYO3A | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NBPF4 | c.1466A>C p.D489A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- NCBP1 | c.722del p.K241Rfs*10 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- NDUFC2 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXNA2 | c.4661-1G>A p.X1554_splice | Splice Site (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- PPWD1 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKN | c.301A>C p.S101R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); called by muse, mutect2
- PURG | c.518C>G p.T173R | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- RAB27B | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SCAI | c.1757T>C p.L586S (on ENST00000336505 / NM_001144877.3; = p.L609S on NM_173690.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC12A8 | c.1961C>G p.S654C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- SLC25A15 | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.59); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC25A43 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SLCO1B3 | c.1745T>C p.L582P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLITRK3 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF587B | c.483dup p.K162* | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- ZNF84 | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC2L | c.252G>A p.V84= | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- GPR12 | c.420C>T p.L140= | Silent (SNP) | VAF 6/31 reads (19%) | called by mutect2, varscan2
- MALRD1 | c.5544G>A p.T1848= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs531402391; called by muse, mutect2, varscan2
- SLC45A4 | c.1845C>T p.Y615= (on ENST00000517878 / NM_001286646.2; = p.Y564= on NM_001080431.2) | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1352275230, COSV50201774; called by muse, mutect2, varscan2
- STK36 | c.999G>A p.K333= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV55328887; called by muse, mutect2, varscan2
- TTC23L | c.909G>A p.L303= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs1309760626; called by muse, mutect2
- AC107023.1 | n.25+3079C>G | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- ANO5 | c.*17G>A | 3'UTR (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- GNE | c.*1089G>A | 3'UTR (SNP) | VAF 12/15 reads (80%) | called by muse, mutect2
- LINC01537 | n.167G>T | RNA (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
